Gene-level copy-number profile of tumor specimen ALCH-B1QB-TTR1-A from ALCHEMIST case ALCH-B1QB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.7 years (24,720 days).
Specimen ALCH-B1QB-TTR1-A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f1d06297-87f6-4dc0-bdf3-e0555f7072ad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1QB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/604687c6-4d85-49df-8052-f268797a9d68

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 1,205; copy number 2: 43,516; copy number 3: 11,311; copy number 4: 1,997; copy number 5: 269; copy number 6: 15; copy number 7: 41; copy number 8: 10; copy number 10: 9.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:139,108,430–139,508,971, 4 genes: AC100807.1, AC100807.2, AC087354.1, AC090093.1.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr12:106,063,340–106,140,033, 2 genes: NUAK1, AC011595.1.
- chr12:108,129,288–108,250,537, 1 gene: WSCD2.
- chr22:26,858,634–26,968,763, 1 gene (within-gene range 0–2): LINC01422.
- chr22:26,903,292–26,920,935, 1 gene: Z97353.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 338 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,259,518–28,335,965, 2 genes, copy number 5: SESN2, MED18.
- chr1:151,008,420–151,249,536, 16 genes, copy number 5: PRUNE1, RNU6-884P, BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A.
- chr1:175,921,975–176,447,919, 11 genes, copy number 5: RPS29P5, COP1, SCARNA3, AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7.
- chr5:58,198–2,262,023, 76 genes, copy number 5 (broad region; genes not listed).
- chr5:12,297,399–25,716,715, 167 genes, copy number 5–10 (broad region; genes not listed).
- chr5:69,875,271–69,985,501, 3 genes, copy number 7: GUSBP13, AC131392.1, CDH12P2.
- chr5:172,958,729–173,164,387, 10 genes, copy number 5 (within-gene range 4–5): RPL26L1, AC008429.2, ATP6V0E1, AC008429.4, SNORA74B, Y_RNA, CREBRF, CDC42P5, AC008378.1, BNIP1.
- chr7:129,830,732–129,952,960, 1 gene, copy number 5: UBE2H.
- chr7:140,404,058–140,479,536, 3 genes, copy number 5 (within-gene range 3–5): RAB19, AC069335.1, MKRN1.
- chr8:42,391,624–42,405,937, 1 gene, copy number 5: VDAC3.
- chr8:42,896,946–43,494,762, 23 genes, copy number 5 (within-gene range 4–5): HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4.
- chr9:61,868,727–61,911,022, 3 genes, copy number 7: AL391987.3, Y_RNA, FAM242E.
- chr10:38,452,987–38,466,176, 2 genes, copy number 5: CICP9, AL133216.1.
- chr11:48,880,111–48,902,181, 3 genes, copy number 6: AC027369.6, AC027369.3, AC027369.4.
- chr12:51,281,038–51,324,668, 1 gene, copy number 5: BIN2.
- chr16:4,616,493–4,767,624, 11 genes, copy number 5–6: MGRN1, RN7SL850P, AC023830.1, Metazoa_SRP, MIR6769A, NUDT16L1, ANKS3, AC020663.1, C16orf71, ZNF500, Metazoa_SRP.
- chr16:18,788,063–18,937,043, 5 genes, copy number 5 (within-gene range 4–5): AC138811.2, ARL6IP1, AC138811.1, SMG1, AC092287.1.

Autosomal genes at a single copy (total copy number 1): 1,200. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
